FM case AD7135 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/50792522-f2d9-452b-a4f4-7d855d77e46e

Female, 77.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
